Somatic mutation profile of tumor specimen MBCProject_3154_T1_WES (aliquot MBCProject_3154_T1_WES_1) from CMI case MBCProject_3154, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 33.0 years (12,063 days).
Specimen MBCProject_3154_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32f1f3be-3489-4973-959a-ede7c9fcab1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3154_SALIVA (Saliva), aliquot MBCProject_3154_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/417424aa-b491-4fa6-a742-97ed3c353f52

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLC1 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV61416756; called by muse, mutect2, varscan2
- KCNU1 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.166); catalogued as COSV67758618; called by muse, mutect2
- LILRB5 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100300458; called by muse, mutect2, varscan2
- MTMR4 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 47/640 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.657); catalogued as rs775203610, COSV60203997; called by muse, mutect2
- AL662899.2 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); called by muse, mutect2
- C5orf51 | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 29/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CARMIL2 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); called by muse, mutect2
- CHD5 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- KLHL33 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 15/245 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- ALG10 | c.1086T>C p.V362= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- OTOP2 | c.1104C>T p.D368= | Silent (SNP) | VAF 160/280 reads (57%) | catalogued as rs768778471, COSV58882465; called by muse, mutect2, varscan2
- PACS2 | c.2391G>A p.T797= | Silent (SNP) | VAF 23/210 reads (11%) | catalogued as rs1295485158; called by muse, mutect2, varscan2
- RBSN | c.1519C>T p.L507= | Silent (SNP) | VAF 30/304 reads (10%) | called by muse, mutect2, varscan2
- LIPC | c.88+4714_88+4715dup | Intron (INS) | VAF 28/240 reads (12%) | called by pindel, varscan2
